Somatic mutation profile of tumor specimen TCGA-B5-A11O-01A (aliquot TCGA-B5-A11O-01A-11D-A122-09) from TCGA case TCGA-B5-A11O, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 62.2 years (22,720 days).
Specimen TCGA-B5-A11O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f19b43e-7058-4834-9a1d-50b4d229d2a8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A11O-10A (Blood Derived Normal), aliquot TCGA-B5-A11O-10A-01D-A122-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ad54b98-6fba-4f2a-8297-d41919af759a

The open-access MAF lists 92 somatic variants for this specimen: 73 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 17, Nonsense Mutation 5, Frame Shift Del 5, In Frame Del 1, Translation Start Site 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ESCO2 | c.760del p.T254Lfs*13 | Frame Shift Del (DEL) | VAF 22/128 reads (17%) | catalogued as rs80359852; ClinVar: pathogenic; called by mutect2, varscan2
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 72/407 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- LAMA2 | c.3829C>T p.R1277* | Nonsense Mutation (SNP) | VAF 36/232 reads (16%) | catalogued as rs1554269891, COSV70354446; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MAX | c.83A>G p.H28R | Missense Mutation (SNP) | VAF 78/408 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV52415800; called by muse, mutect2, varscan2
- PIK3CA | c.1636C>A p.Q546K | Missense Mutation (SNP) | VAF 41/230 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as rs121913286, COSV55873527, COSV55882350; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 65/395 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.968del p.N323Mfs*21 | Frame Shift Del (DEL) | VAF 34/248 reads (14%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ADCY8 | c.1994A>G p.E665G | Missense Mutation (SNP) | VAF 19/364 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.579); catalogued as COSV53902561, COSV53925379; called by muse, mutect2
- ADGRG2 | c.677C>G p.P226R (on ENST00000379869 / NM_001079858.3; = p.P223R on NM_005756.4) | Missense Mutation (SNP) | VAF 22/312 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.806); catalogued as COSV61341077; called by muse, mutect2
- AFP | c.746A>G p.K249R | Missense Mutation (SNP) | VAF 37/215 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as COSV56926882; called by muse, mutect2, varscan2
- ALKBH2 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 22/424 reads (5%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV54358766, COSV54358792; called by muse, mutect2
- ARID1A | c.1776T>G p.Y592* | Nonsense Mutation (SNP) | VAF 18/104 reads (17%) | catalogued as COSV61383348, COSV61388053; called by muse, mutect2
- ARID1A | c.4917del p.T1640Pfs*14 | Frame Shift Del (DEL) | VAF 9/30 reads (30%) | catalogued as COSV61388060; called by mutect2, pindel, varscan2
- ATCAY | c.1004C>T p.A335V | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs112396816, COSV56658817; called by muse, mutect2, varscan2
- ATXN2 | c.1580G>T p.R527I (on ENST00000550104; = p.R367I on NM_002973.4) | Missense Mutation (SNP) | VAF 35/202 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66485822, COSV66485865; called by muse, mutect2, varscan2
- BAG3 | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as rs748451757, COSV64842622; called by muse, mutect2, varscan2
- CCDC85A | c.414C>A p.H138Q | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.137); catalogued as COSV68155239; called by muse, mutect2, varscan2
- CDCA7L | c.448A>G p.T150A | Missense Mutation (SNP) | VAF 47/239 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.048); catalogued as rs768997741, COSV62261350; called by muse, mutect2, varscan2
- CDH12 | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 106/534 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.035); catalogued as rs143124599, COSV66443827; called by muse, mutect2, varscan2
- CDH24 | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769146602, COSV52981660; called by muse, mutect2, varscan2
- EIF2AK2 | c.1501G>T p.G501C | Missense Mutation (SNP) | VAF 61/321 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.742); catalogued as COSV51798943; called by muse, mutect2, varscan2
- EZHIP | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV57957527; called by muse, mutect2, varscan2
- FAM13B | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 80/390 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as rs775718846, COSV50365761; called by muse, mutect2, varscan2
- FBXO38 | c.413G>A p.C138Y | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs949714933, COSV57031129; called by muse, mutect2
- FEM1C | c.1198G>A p.G400S | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.563); catalogued as COSV57232693; called by muse, mutect2, varscan2
- FRAS1 | c.4033A>G p.M1345V | Missense Mutation (SNP) | VAF 57/272 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.471); catalogued as COSV53643375; called by muse, mutect2, varscan2
- GLI2 | c.4268C>T p.P1423L (on ENST00000361492 / NM_001374353.1; = p.P1440L on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs267598856, COSV58035796; called by muse, mutect2, varscan2
- GLP2R | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 48/315 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs575133662, COSV52324255; called by muse, mutect2, varscan2
- GNPTG | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.511); catalogued as rs778810991, COSV50190775; called by muse, mutect2, varscan2
- GNS | c.231G>T p.M77I | Missense Mutation (SNP) | VAF 42/282 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV50694054, COSV50696540; called by muse, mutect2, varscan2
- GPR101 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as rs1177295791, COSV53240245; called by muse, mutect2
- GPR87 | c.1073T>C p.V358A | Missense Mutation (SNP) | VAF 45/262 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.108); catalogued as COSV53464390; called by muse, mutect2, varscan2
- GPS2 | c.91C>T p.Q31* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | catalogued as COSV59753098; called by muse, mutect2, varscan2
- GRIPAP1 | c.315C>A p.S105R | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as COSV64553293; called by muse, mutect2
- HMGB3 | c.511G>C p.G171R | Missense Mutation (SNP) | VAF 29/355 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV57487224; called by muse, mutect2
- HOGA1 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as rs1187011297, COSV65706256; called by muse, mutect2, varscan2
- HTN1 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.975); catalogued as rs552053383, COSV55895457; called by muse, mutect2, varscan2
- IL27 | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs373848919, COSV60494496; called by muse, mutect2, varscan2
- KMT2A | c.7864C>T p.R2622C | Missense Mutation (SNP) | VAF 9/192 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV63292072; called by muse, mutect2
- LRP1B | c.4735G>A p.A1579T | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as COSV67269591; called by muse, mutect2
- MACF1 | c.15988A>G p.K5330E (on ENST00000372915; = p.K3263E on NM_012090.5) | Missense Mutation (SNP) | VAF 36/178 reads (20%) | catalogued as COSV57141601; called by muse, mutect2, varscan2
- MAP1S | c.2893G>T p.E965* | Nonsense Mutation (SNP) | VAF 3/49 reads (6%) | catalogued as COSV60723023; called by muse, mutect2
- MEGF6 | c.4605C>A p.S1535R | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV53895356; called by muse, mutect2
- MKI67 | c.8775_8776del p.Q2926Nfs*6 | Frame Shift Del (DEL) | VAF 67/426 reads (16%) | catalogued as rs1173089014; called by pindel, varscan2
- MON1A | c.1538G>A p.R513H | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1434723495, COSV56562744; called by muse, mutect2, varscan2
- MUC17 | c.8154C>G p.D2718E | Missense Mutation (SNP) | VAF 78/420 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV60298358, COSV60302081; called by muse, mutect2, varscan2
- MYO15A | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 10/268 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.125); catalogued as COSV52765014; called by muse, mutect2
- NLRP10 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.721); catalogued as rs529453927, COSV60781142; called by muse, mutect2, varscan2
- NUMA1 | c.5642G>A p.R1881H | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs777276380, COSV52622610; called by muse, mutect2, varscan2
- OGFOD3 | c.316C>T p.R106* | Nonsense Mutation (SNP) | VAF 6/43 reads (14%) | catalogued as rs778238763, COSV57343182; called by muse, mutect2, varscan2
- PCDHA5 | c.1387G>A p.V463M | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as rs781947954, COSV65352974; called by muse, mutect2, varscan2
- PCDHGA12 | c.1910C>T p.A637V | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.166); catalogued as COSV52754284; called by muse, mutect2, varscan2
- PFKL | c.2117C>T p.S706L | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as rs753053886, COSV57395337, COSV57395615; called by muse, mutect2, varscan2
- PLEC | c.787G>A p.A263T (on ENST00000322810 / NM_201380.4; = p.A153T on NM_000445.5) | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0.074); catalogued as rs782389278, COSV59691100; called by muse, mutect2
- PRKAG2 | c.1367G>A p.R456Q | Missense Mutation (SNP) | VAF 88/492 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.599); catalogued as rs730880980, COSV55228535; ClinVar: uncertain significance; called by muse, varscan2
- RNF123 | c.2312G>A p.G771D | Missense Mutation (SNP) | VAF 23/256 reads (9%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.881); catalogued as COSV59692113; called by muse, mutect2
- ROBO4 | c.1472G>A p.R491H | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.635); catalogued as rs371541640; called by mutect2, varscan2
- SCN1A | c.1481C>T p.A494V | Missense Mutation (SNP) | VAF 16/447 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV57685237; called by muse, mutect2
- SPATA31D1 | c.1910G>C p.W637S | Missense Mutation (SNP) | VAF 133/652 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); catalogued as COSV61200822; called by muse, mutect2, varscan2
- SSRP1 | c.1159C>G p.R387G | Missense Mutation (SNP) | VAF 44/227 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV53479743, COSV53481404; called by muse, mutect2, varscan2
- SYT12 | c.1231C>T p.P411S | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67354852; called by muse, mutect2, varscan2
- TJAP1 | c.757G>A p.G253R (on ENST00000372445 / NM_001146016.1; = p.G243R on NM_080604.3) | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as rs151036953; called by muse, mutect2, varscan2
- TLE1 | c.1852G>A p.G618R | Missense Mutation (SNP) | VAF 24/204 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64719361, COSV64719460, COSV64723155; called by muse, mutect2, varscan2
- TSHZ3 | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53681313; called by muse, mutect2, varscan2
- TTC7B | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 52/336 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as rs762188010, COSV60638384; called by muse, mutect2, varscan2
- TYW5 | c.649T>C p.Y217H | Missense Mutation (SNP) | VAF 41/425 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as COSV63562893; called by muse, mutect2
- VPS35L | c.2111G>A p.C704Y | Missense Mutation (SNP) | VAF 18/343 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51990757; called by muse, mutect2
- VPS41 | c.1316T>G p.I439S | Missense Mutation (SNP) | VAF 69/283 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.155); catalogued as COSV59652649; called by muse, mutect2, varscan2
- WDPCP | c.2180G>T p.G727V | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV55431373, COSV55432687; called by muse, mutect2, varscan2
- XYLB | c.793C>A p.R265S | Missense Mutation (SNP) | VAF 26/361 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52915640; called by muse, mutect2
- ZCCHC14 | c.364T>C p.W122R (on ENST00000268616; = p.W259R on NM_015144.3) | Missense Mutation (SNP) | VAF 9/271 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51890053; called by muse, mutect2
- BIRC6 | c.4304_4306del p.N1435del | In Frame Del (DEL) | VAF 82/486 reads (17%) | called by pindel, varscan2
- ZNF292 | c.3460_3463del p.V1154Ifs*7 | Frame Shift Del (DEL) | VAF 15/99 reads (15%) | called by pindel, varscan2
- ADH5 | c.432C>T p.S144= | Silent (SNP) | VAF 12/240 reads (5%) | catalogued as rs1292485252, COSV56448975; called by muse, mutect2
- ADPGK | c.279G>A p.L93= | Silent (SNP) | VAF 14/114 reads (12%) | catalogued as rs1451393656, COSV100295240, COSV61175020; called by muse, mutect2, varscan2
- ATAD2 | c.1666C>T p.L556= | Silent (SNP) | VAF 52/280 reads (19%) | catalogued as COSV54886059; called by muse, mutect2, varscan2
- B4GALT1 | c.216G>A p.Q72= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV65708943; called by muse, mutect2
- CSMD1 | c.6315C>T p.S2105= (on ENST00000520002; = p.S2104= on NM_033225.6) | Silent (SNP) | VAF 50/325 reads (15%) | catalogued as rs752068472, COSV59339100, COSV59377096; called by muse, mutect2, varscan2
- GIGYF1 | c.1773G>A p.L591= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV51946399; called by muse, mutect2, varscan2
- IRX1 | c.543G>A p.A181= | Silent (SNP) | VAF 32/206 reads (16%) | catalogued as COSV57358819; called by muse, mutect2, varscan2
- ISY1 | c.669C>T p.D223= | Silent (SNP) | VAF 40/264 reads (15%) | catalogued as rs375151571; called by muse, mutect2, varscan2
- KCNF1 | c.1158C>T p.N386= | Silent (SNP) | VAF 37/169 reads (22%) | catalogued as rs1429456401, COSV54465483; called by muse, mutect2, varscan2
- MYH6 | c.2097C>T p.G699= | Silent (SNP) | VAF 25/166 reads (15%) | catalogued as rs149734381; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- OR5T2 | c.834C>T p.S278= | Silent (SNP) | VAF 55/306 reads (18%) | catalogued as rs1235850143, COSV57590790; called by muse, mutect2
- POLQ | c.7446A>G p.K2482= | Silent (SNP) | VAF 23/588 reads (4%) | called by muse, mutect2
- SCARB2 | c.126G>A p.V42= | Silent (SNP) | VAF 5/93 reads (5%) | catalogued as COSV53670375; called by muse, mutect2
- TNFSF8 | c.549G>A p.T183= | Silent (SNP) | VAF 103/572 reads (18%) | catalogued as rs373154083; called by muse, mutect2, varscan2
- TTN | c.34170A>G p.K11390= (on ENST00000591111; = p.K10463= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 121/613 reads (20%) | catalogued as rs750096348, COSV60310801; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF229 | c.1809C>T p.D603= | Silent (SNP) | VAF 26/125 reads (21%) | catalogued as rs1049126453, COSV52164604; called by muse, mutect2, varscan2
- ZSWIM8 | c.3627G>A p.A1209= (on ENST00000605216 / NM_001242487.2; = p.A1214= on NM_015037.3) | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as rs550418129, COSV55217579; called by mutect2, varscan2
- PYY3 | n.8C>T | RNA (SNP) | VAF 9/94 reads (10%) | catalogued as rs990277254; called by muse, mutect2, varscan2
- ZNF556 | c.*2G>T | 3'UTR (SNP) | VAF 7/36 reads (19%) | catalogued as COSV100298827; called by muse, mutect2, varscan2
